Somatic mutation profile of tumor specimen TARGET-20-PAKKBK-09A (aliquot TARGET-20-PAKKBK-09A-01D) from TARGET case TARGET-20-PAKKBK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (705 days).
Specimen TARGET-20-PAKKBK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 323fd9fc-af7e-4d44-ace6-1ca65c253ee4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PAKKBK-14A (Bone Marrow Normal), aliquot TARGET-20-PAKKBK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67a870a3-5af8-460a-b3a9-faa0d8a4b4fa

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 84/149 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs774800014, COSV53914076; called by muse, mutect2, varscan2
- NFE2L3 | c.1861_1862del p.K621Efs*7 | Frame Shift Del (DEL) | VAF 5/41 reads (12%) | catalogued as rs777869574, COSV50227502; called by mutect2, pindel, varscan2
- RNF150 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as rs376456097; called by muse, mutect2, varscan2
- SATB1 | c.180_181insACGGACCCCTG p.G61Tfs*7 | Frame Shift Ins (INS) | VAF 67/202 reads (33%) | called by mutect2, pindel, varscan2
- UCP1 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 75/683 reads (11%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BCS1L | c.117C>T p.G39= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV55308220; called by mutect2, varscan2
